Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8381, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8381-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: Stomach part with saucer-like tumor up to 5x4.5 cm in size, with invasion into the perigastric fat tissue. In the fatty tissue there are hyperemic lymph nodes up to 0.6 cm in size. Omentum is of normal structure.

Microscopic Description: Gastric adenocarcinoma, G-3, with invasion into the fatty tissue. One from fifteen examined lymph nodes demonstrated metastasis.

Diagnosis Details: Tumor Features: Ulcerated, Tumor Extent: Perigastric fat, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Fundus

Tumor size: 4.5 x 0 x 5 cm

Tumor features: Ulcerated

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Subserosa

Lymph nodes: 1/15 positive for metastasis (Greater and lesser curvature. 1/15)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: fundus C16.1
hu
11/5/13

Source: NCI Genomic Data Commons file 3cd1fcc6-012d-430e-b211-04b45902c487 (TCGA-BR-8381.C6F1CEC0-F54F-40D8-9946-1E20844B3C6F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).